FM case AD879 — Foundation Medicine Adult Cancer Clinical Dataset (FM-AD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Adenomas and Adenocarcinomas; Primary site: Cervix uteri.
https://portal.gdc.cancer.gov/cases/280cafd2-46b9-4824-855c-e1d1b3976658

Female, 40.9 years: Adenocarcinoma, NOS (ICD-O-3 8140/3) of the cervix uteri; metastasis biopsied or resected from the lung. Tumor nuclei on the sequenced sample's slide: 60% (pathologist estimate recorded by GDC). Sample type: Metastatic.
